Somatic mutation profile of tumor specimen TCGA-EO-A3AV-01A (aliquot TCGA-EO-A3AV-01A-12D-A19Y-09) from TCGA case TCGA-EO-A3AV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 51.2 years (18,713 days).
Specimen TCGA-EO-A3AV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a131e487-84d9-4469-814d-82461aab6313.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EO-A3AV-10A (Blood Derived Normal), aliquot TCGA-EO-A3AV-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0236be4a-6348-4669-a29b-b3e0a23b8454

The open-access MAF lists 4,600 somatic variants for this specimen: 3,669 protein-altering or splice-affecting, 803 silent, 128 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,117, Silent 803, Nonsense Mutation 461, Splice Site 52, Intron 44, RNA 41, Splice Region 20, 5'Flank 17, 3'UTR 10, 5'UTR 9, Nonstop Mutation 7, 3'Flank 7.

Variants (750 of 4,600; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAD9 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753711253, COSV100458917; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANOS1 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as rs727505374, CM015287, COSV99390378; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.8737G>T p.D2913Y | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756899044, CM121262, COSV99587069, COSV99588756; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP6AP1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs878853277, CM166855, COSV63895463; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDKL5 | c.2095G>T p.E699* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as rs886041673, COSV101184005; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD4 | c.3341G>A p.R1114Q (on ENST00000357008 / NM_001363606.2; = p.R1127Q on NM_001273.5) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs886039917, COSV58895679; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL17A1 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as rs121912774, CM001969, COSV62225489; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.8944C>T p.R2982* | Nonsense Mutation (SNP) | VAF 9/60 reads (15%) | catalogued as rs128625229, CM920238, COSV100625881; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNAH8 | c.10951C>T p.R3651* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as rs769929539, COSV59438495; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EZH2 | c.2218G>A p.E740K (on ENST00000460911 / NM_001203247.2; = p.E745K on NM_004456.5) | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs397515548, CM1110546, COSV57447594, COSV57464742; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.8335G>T p.E2779* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as rs1555393551, COSV100353965, COSV57309148; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGF16 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as rs587777050, CM137753, COSV101466309; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIT | c.1598C>A p.A533D | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs753212327, CM041384, COSV55388009, COSV55410611; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.15535C>T p.R5179C | Missense Mutation (SNP) | VAF 3/23 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs794727688, CM1410247, COSV56425613, COSV56431676; ClinVar: pathogenic; called by muse, mutect2
- NF1 | c.4084C>T p.R1362* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as rs137854560, CM971046, COSV62191433, COSV62213078; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 8/53 reads (15%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519929, CM126687, COSV55873676, COSV55913749; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 7/33 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- POLR1C | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.764); catalogued as rs373046018, CM157296; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as rs1554890335, COSV64288471, COSV64291810; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as rs121913296, CM961221, COSV57300832; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RPGR | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as rs62635001, CM971314, COSV100139548; ClinVar: not provided / likely pathogenic; called by muse, mutect2
- RTKN2 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | hotspot (GDC flag); catalogued as rs772033296, COSV65679700, COSV65679972; called by muse, mutect2, varscan2
- RUNX1 | c.780C>A p.Y260* (on ENST00000344691 / NM_001001890.3; = p.Y287* on NM_001754.5) | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | catalogued as rs121912499, CM025983, COSV100276401, COSV55888341; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs794728708, CM010421, COSV63694898; ClinVar: pathogenic; called by mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SUZ12 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 14/82 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs1443094716, COSV59498812; called by muse, mutect2, varscan2
- TCF4 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as rs878853149, CM120282, COSV61890253; ClinVar: pathogenic; called by muse, mutect2, varscan2
- THPO | c.532C>T p.R178C (on ENST00000649095 / NM_001290003.1; = p.R38C on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760797899, CM1312033, COSV52605324; ClinVar: likely pathogenic; called by muse, mutect2
- TSHR | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772490052, COSV53315668; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TUBA1A | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as rs1057517858, CM103939, COSV55496874, COSV55497525; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.2467C>T p.R823W | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as rs372194305, COSV59394128; called by muse, mutect2, varscan2
- A2ML1 | c.1609T>G p.Y537D | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100228471; called by muse, varscan2
- AARS2 | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99771192; called by muse, mutect2, varscan2
- AASS | c.1322C>A p.S441Y | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV100741643, COSV104416546; called by muse, mutect2
- AASS | c.1228G>T p.E410* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100741644; called by muse, mutect2, varscan2
- ABCA1 | c.6731T>A p.V2244D | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.276); catalogued as rs1466911823, COSV101036452; called by muse, mutect2, varscan2
- ABCA12 | c.5498A>C p.K1833T (on ENST00000272895 / NM_173076.3; = p.K1515T on NM_015657.3) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.023); catalogued as COSV99788097; called by muse, mutect2, varscan2
- ABCA12 | c.5345C>A p.S1782Y (on ENST00000272895 / NM_173076.3; = p.S1464Y on NM_015657.3) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV99788101; called by muse, mutect2, varscan2
- ABCA12 | c.2725G>A p.D909N (on ENST00000272895 / NM_173076.3; = p.D591N on NM_015657.3) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.102); catalogued as rs767059932, COSV55963360; called by muse, mutect2, varscan2
- ABCA12 | c.2025G>T p.E675D (on ENST00000272895 / NM_173076.3; = p.E357D on NM_015657.3) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as CD065656, COSV99788104; called by muse, mutect2, varscan2
- ABCA13 | c.1051G>A p.V351I | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.108); catalogued as rs1440624235, COSV101329907; called by muse, mutect2, varscan2
- ABCA13 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.742); catalogued as COSV101329908; called by muse, mutect2, varscan2
- ABCA13 | c.3378A>C p.Q1126H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV70025734; called by mutect2, varscan2
- ABCA13 | c.3925C>A p.L1309I | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101329909; called by muse, mutect2, varscan2
- ABCA13 | c.4702A>C p.N1568H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as COSV101329910; called by muse, mutect2
- ABCA13 | c.7406G>T p.R2469I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV101446731; called by muse, mutect2, varscan2
- ABCA13 | c.8525G>T p.R2842I | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV71286080, COSV71288716; called by muse, mutect2, varscan2
- ABCA13 | c.13602G>T p.K4534N | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs202160840, COSV68949410; called by muse, mutect2, varscan2
- ABCA6 | c.3376A>C p.N1126H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as rs1370594607, COSV99445706; called by muse, mutect2, varscan2
- ABCA6 | c.750G>T p.K250N | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99445708; called by muse, mutect2, varscan2
- ABCA8 | c.4564G>T p.A1522S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99284640; called by muse, mutect2, varscan2
- ABCA8 | c.642C>A p.F214L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV52208844, COSV99284643; called by muse, mutect2, varscan2
- ABCB1 | c.1984C>A p.L662I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99712017; called by mutect2, varscan2
- ABCB4 | c.3280-1G>T p.X1094_splice | Splice Site (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99709638; called by muse, mutect2
- ABCB4 | c.1561-1G>T p.X521_splice | Splice Site (SNP) | VAF 13/39 reads (33%) | catalogued as COSV99709639; called by muse, mutect2, varscan2
- ABCB4 | c.853A>C p.N285H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV99709641; called by muse, mutect2, varscan2
- ABCB7 | c.1330T>G p.L444V (on ENST00000373394 / NM_001271696.3; = p.L445V on NM_004299.6) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV99503854; called by muse, mutect2, varscan2
- ABCB7 | c.23C>A p.S8Y | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.009); catalogued as COSV53722774, COSV99503857; called by muse, mutect2, varscan2
- ABCB9 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | catalogued as rs778779329, COSV99757530; called by muse, mutect2, varscan2
- ABCC11 | c.1959G>T p.Q653H | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV62323493, COSV62323988; called by muse, mutect2, varscan2
- ABCC12 | c.1120G>A p.A374T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.846); catalogued as rs917072595, COSV100252119; called by muse, mutect2, varscan2
- ABCC2 | c.1495T>G p.L499V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.377); catalogued as COSV100966372; called by muse, mutect2, varscan2
- ABCC2 | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs1371262907, COSV100966374; called by muse, mutect2, varscan2
- ABCC2 | c.2731C>T p.R911* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as rs756825916, COSV64985495; called by muse, mutect2, varscan2
- ABCC2 | c.4100C>T p.S1367F | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100966377; called by muse, mutect2, varscan2
- ABCC4 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs267603866, COSV100972205; called by muse, mutect2, varscan2
- ABCC8 | c.1182G>T p.K394N | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.285); catalogued as rs1210394340, COSV100216542; called by muse, mutect2, varscan2
- ABCE1 | c.782C>A p.S261Y | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as rs972142567, COSV99668354; called by muse, mutect2, varscan2
- ABCF3 | c.106T>C p.S36P | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.794); catalogued as COSV99490272; called by muse, mutect2, varscan2
- ABCF3 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99491214; called by muse, mutect2, varscan2
- ABCF3 | c.1742A>C p.K581T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as COSV99491219; called by mutect2, varscan2
- ABCG2 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV52942746, COSV52947706; called by muse, mutect2, varscan2
- ABHD11 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as rs782113507, COSV56105339; called by muse, mutect2, varscan2
- ABHD5 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as COSV99185453; called by muse, mutect2, varscan2
- ABR | c.1147A>C p.K383Q (on ENST00000302538 / NM_021962.5; = p.K346Q on NM_001092.5) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99347396; called by muse, mutect2, varscan2
- AC005833.1 | c.990G>T p.E330D | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV99362446; called by muse, mutect2, varscan2
- AC098582.1 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199802317, COSV52026263, COSV99985244; called by muse, mutect2, varscan2
- AC100868.1 | c.1439C>A p.S480Y | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs766366784, COSV51839810, COSV99225154; called by muse, mutect2
- AC109583.1 | c.362C>A p.A121D | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100167772; called by muse, mutect2, varscan2
- ACADL | c.603+2T>C p.X201_splice | Splice Site (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99284515; called by muse, mutect2, varscan2
- ACAT2 | c.1087C>A p.L363I | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV100364906, COSV58457385; called by muse, mutect2, varscan2
- ACCS | c.1158G>T p.K386N | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV99772634; called by muse, mutect2, varscan2
- ACLY | c.346-2A>C p.X116_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100709499; called by muse, mutect2
- ACMSD | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99298768; called by muse, mutect2, varscan2
- ACMSD | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99298773; called by muse, mutect2, varscan2
- ACOT13 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs370510266; called by mutect2, varscan2
- ACOT8 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.116); catalogued as rs1230413648, COSV54172147; called by muse, mutect2, varscan2
- ACOX3 | c.424A>C p.T142P | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100711812, COSV62712150, COSV62712639; called by muse, mutect2, varscan2
- ACP2 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs138968159; called by muse, mutect2, varscan2
- ACP3 | c.1109C>T p.T370M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs761910783, COSV100313090; called by mutect2, varscan2
- ACP5 | c.40T>G p.L14V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99520170; called by muse, mutect2, varscan2
- ACP6 | c.1284G>T p.E428D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.073); catalogued as COSV100984156; called by muse, mutect2
- ACSBG1 | c.557G>A p.G186D | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99356993; called by muse, mutect2, varscan2
- ACSM2A | c.80G>A p.S27N | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs762115260, COSV99524834; called by muse, mutect2, varscan2
- ACSM2B | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100312278; called by muse, mutect2, varscan2
- ACSM3 | c.230A>G p.K77R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99184035; called by muse, mutect2
- ACSM4 | c.599T>C p.L200P | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as COSV101256999; called by muse, mutect2, varscan2
- ACTG2 | c.806-1G>A p.X269_splice | Splice Site (SNP) | VAF 16/53 reads (30%) | catalogued as COSV100608842; called by muse, mutect2, varscan2
- ACTR2 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as COSV53199572, COSV53201772; called by muse, varscan2
- ACTR2 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as COSV53200653; called by muse, varscan2
- ACTR3 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV54302653; called by muse, mutect2, varscan2
- ACTR3B | c.224A>C p.K75T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.89); catalogued as COSV99753535; called by muse, mutect2, varscan2
- ACVR2B | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.233); catalogued as COSV61703030; called by muse, mutect2, varscan2
- ADAD1 | c.16C>A p.H6N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99635026; called by muse, mutect2
- ADAM7 | c.1895A>C p.N632T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV99442915; called by muse, mutect2, varscan2
- ADAMTS14 | c.1545C>A p.F515L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV100941324, COSV64602821; called by muse, mutect2, varscan2
- ADAMTS19 | c.2776A>G p.T926A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV99176280; called by muse, mutect2, varscan2
- ADAMTS20 | c.4135A>C p.K1379Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.949); catalogued as COSV101166053; called by muse, mutect2, varscan2
- ADAMTS3 | c.2267A>C p.K756T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99710080; called by muse, mutect2, varscan2
- ADAMTS3 | c.589A>G p.I197V | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99710081; called by muse, mutect2, varscan2
- ADAP2 | c.742-1G>T p.X248_splice | Splice Site (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100437140; called by muse, mutect2, varscan2
- ADAR | c.1741T>G p.S581A | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.024); catalogued as COSV99425426; called by mutect2, varscan2
- ADAR | c.137T>G p.F46C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99425430; called by muse, mutect2, varscan2
- ADCK2 | c.1825G>T p.D609Y | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99199959; called by muse, mutect2, varscan2
- ADCY1 | c.2734T>G p.F912V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.271); catalogued as COSV99811196; called by muse, mutect2
- ADCY3 | c.2918A>C p.K973T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99567592; called by mutect2, varscan2
- ADCY8 | c.1098G>T p.E366D | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV53933009, COSV99650580; called by muse, mutect2, varscan2
- ADGRA1 | c.1036A>G p.T346A | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV100811000; called by muse, mutect2, varscan2
- ADGRB2 | c.2647G>T p.D883Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV99925634; called by muse, mutect2, varscan2
- ADGRB3 | c.3368A>C p.K1123T | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV99483337; called by muse, mutect2, varscan2
- ADGRE1 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs149695793; called by muse, varscan2
- ADGRG4 | c.2950G>T p.D984Y | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.675); catalogued as COSV99794248; called by muse, mutect2, varscan2
- ADGRL2 | c.2057T>G p.F686C (on ENST00000370717 / NM_001366005.1; = p.F673C on NM_012302.4) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99586953; called by muse, mutect2, varscan2
- ADGRL3 | c.1256G>T p.S419I (on ENST00000506720 / NM_001322402.2; = p.S351I on NM_015236.6) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.405); catalogued as COSV101546829; called by muse, mutect2, varscan2
- ADGRL4 | c.845T>G p.F282C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV100875548; called by muse, mutect2, varscan2
- ADGRV1 | c.3331A>C p.I1111L | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV101315428; called by muse, mutect2, varscan2
- ADGRV1 | c.14605C>A p.L4869I | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV101315430; called by muse, mutect2, varscan2
- ADNP | c.2021A>G p.N674S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as COSV100823632; called by muse, mutect2, varscan2
- ADTRP | c.546T>G p.Y182* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99995012; called by muse, mutect2, varscan2
- AFDN | c.3404C>A p.S1135* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100652387; called by muse, mutect2, varscan2
- AFDN | c.4393G>A p.E1465K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); catalogued as rs1439875677, COSV100652390; called by muse, mutect2, varscan2
- AFF2 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 10/70 reads (14%) | catalogued as COSV53983823; called by muse, mutect2, varscan2
- AFTPH | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.735); catalogued as COSV99480262; called by muse, mutect2, varscan2
- AFTPH | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99480263; called by muse, mutect2, varscan2
- AGAP1 | c.1049A>G p.Q350R | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV100363653; called by muse, mutect2, varscan2
- AGAP2 | c.966G>T p.E322D | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.451); catalogued as COSV99222145; called by muse, mutect2, varscan2
- AGK | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as rs139967538; called by muse, mutect2, varscan2
- AGK | c.1096C>T p.L366F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.391); catalogued as COSV100814520; called by muse, mutect2, varscan2
- AGMO | c.294T>G p.I98M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV100693517; called by muse, mutect2, varscan2
- AGO2 | c.785T>G p.I262S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99595174; called by muse, mutect2, varscan2
- AGTR2 | c.205T>C p.F69L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100903523; called by muse, mutect2, varscan2
- AHNAK | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as rs566485366, COSV99945408; called by muse, mutect2, varscan2
- AHNAK2 | c.6625G>A p.D2209N | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); catalogued as rs369804430; called by muse, mutect2, varscan2
- AK5 | c.1262G>T p.R421I (on ENST00000354567 / NM_174858.3; = p.R395I on NM_012093.4) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60967389; called by muse, mutect2, varscan2
- AK9 | c.3274C>A p.L1092I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.318); catalogued as COSV100393043; called by muse, mutect2, varscan2
- AKAP11 | c.4471G>T p.E1491* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99213433; called by muse, mutect2, varscan2
- AKAP12 | c.5021C>A p.S1674Y | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV99482290; called by muse, mutect2
- AKAP3 | c.237A>C p.K79N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV99961736; called by muse, mutect2, varscan2
- AKAP4 | c.2302A>G p.N768D | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.018); catalogued as COSV100654133, COSV100654205; called by muse, mutect2, varscan2
- AKAP6 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV99797987; called by muse, mutect2, varscan2
- AKAP6 | c.3800A>G p.N1267S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99797990; called by muse, mutect2, varscan2
- AKAP7 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV63504692; called by muse, mutect2, varscan2
- AKAP9 | c.1945C>T p.R649* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as rs779398715, COSV62339967; called by mutect2, varscan2
- AKAP9 | c.2534A>C p.K845T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as COSV100661863; called by muse, mutect2
- AKIP1 | c.276C>A p.F92L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.352); catalogued as rs371516259; called by mutect2, varscan2
- AKNA | c.1687A>G p.T563A | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99799572; called by muse, mutect2, varscan2
- AKTIP | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs1394013364, COSV100043254; called by muse, varscan2
- AL121899.2 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.425); catalogued as rs146171554, COSV101198371; called by muse, mutect2, varscan2
- AL592490.1 | c.1818A>C p.R606S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.626); catalogued as COSV101308096; called by muse, mutect2, varscan2
- ALAD | c.612C>A p.F204L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as COSV52958103, COSV99474532; called by muse, mutect2, varscan2
- ALB | c.375C>A p.C125* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99890634; called by muse, mutect2, varscan2
- ALDH7A1 | c.1387G>T p.D463Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100778244; called by muse, mutect2, varscan2
- ALG10 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 26/96 reads (27%) | catalogued as COSV99847889; called by muse, mutect2, varscan2
- ALG11 | c.458G>T p.S153I | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101584236; called by muse, mutect2, varscan2
- ALG13 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 11/71 reads (15%) | catalogued as COSV52634896; called by muse, mutect2, varscan2
- ALG5 | c.135C>A p.F45L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV99523496; called by muse, mutect2, varscan2
- ALK | c.2602C>A p.L868I | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.425); catalogued as COSV101201094; called by muse, mutect2, varscan2
- ALKBH8 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99508427, COSV99508661; called by muse, mutect2, varscan2
- ALOX12B | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1221632429, COSV59875270; called by muse, mutect2, varscan2
- ALPK2 | c.4693C>A p.H1565N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as COSV100864057; called by muse, mutect2, varscan2
- ALPK2 | c.3372G>T p.E1124D | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs917177846, COSV64496789; called by muse, mutect2, varscan2
- ALS2 | c.4528C>T p.R1510* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as rs1391892163, COSV99968674; called by muse, mutect2, varscan2
- ALS2 | c.1511C>T p.T504M | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs747774956, COSV51889758; called by muse, mutect2, varscan2
- ALS2CL | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 18/119 reads (15%) | catalogued as COSV100014713; called by muse, mutect2, varscan2
- AMBN | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV59827212; called by muse, varscan2
- AMOT | c.1916G>T p.R639I (on ENST00000371959 / NM_001113490.1; = p.R230I on NM_133265.3) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100494705; called by muse, mutect2, varscan2
- AMOT | c.1378G>A p.A460T (on ENST00000371959 / NM_001113490.1; = p.A51T on NM_133265.3) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100494707; called by muse, mutect2, varscan2
- AMOTL2 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770749530, COSV51441865; called by muse, mutect2, varscan2
- AMPH | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1348357360, COSV57737817; called by muse, mutect2, varscan2
- AMY1A | c.1003C>T p.L335= | Splice Region (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100915772; called by mutect2, varscan2
- AMY2B | c.1152A>C p.E384D | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100796160; called by muse, mutect2, varscan2
- AMY2B | c.1516C>A p.H506N | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100796471, COSV63716137; called by muse, mutect2, varscan2
- AMZ2 | c.325A>C p.K109Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV100703081; called by muse, mutect2, varscan2
- ANGPT1 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV99861827; called by muse, mutect2, varscan2
- ANGPTL5 | c.785T>C p.F262S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100527611; called by muse, mutect2, varscan2
- ANK2 | c.8273C>A p.S2758Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.074); catalogued as COSV99999399; called by muse, mutect2, varscan2
- ANK2 | c.9164T>C p.F3055S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99999403; called by muse, mutect2, varscan2
- ANK2 | c.9587C>T p.S3196L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.254); catalogued as rs144719173, COSV52190287; called by muse, mutect2, varscan2
- ANK3 | c.3526C>T p.R1176* (on ENST00000280772 / NM_001320874.2; = p.R310* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as rs142673853, COSV55052053; called by muse, mutect2, varscan2
- ANKFN1 | c.107G>A p.R36K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV100593065; called by muse, mutect2, varscan2
- ANKRD17 | c.4673G>T p.R1558I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV58218291; called by muse, mutect2, varscan2
- ANKRD17 | c.2818G>T p.E940* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as COSV100428489; called by muse, mutect2, varscan2
- ANKRD17 | c.2218G>A p.D740N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.801); catalogued as rs1476151741, COSV58224235; called by muse, mutect2, varscan2
- ANKRD24 | c.1209G>T p.E403D | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs1033393657, COSV99516898; called by muse, mutect2, varscan2
- ANKRD26 | c.2069C>A p.S690* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as rs1466589987, COSV101062894, COSV65778968; called by muse, mutect2, varscan2
- ANKRD30A | c.751C>A p.H251N (on ENST00000611781; = p.H195N on NM_052997.2) | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100652838; called by muse, mutect2, varscan2
- ANKRD36B | c.789G>T p.E263D | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99307846; called by muse, mutect2, varscan2
- ANKRD42 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as rs780800417, COSV52615647; called by muse, mutect2, varscan2
- ANKRD44 | c.1388A>G p.N463S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1474930811, COSV99983937; called by muse, mutect2, varscan2
- ANKRD45 | c.30G>T p.E10D | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV100322354, COSV60962534; called by muse, mutect2, varscan2
- ANKRD53 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs1553423818, COSV55537694; called by muse, mutect2, varscan2
- ANKRD55 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs774118271, COSV100591015; called by muse, mutect2, varscan2
- ANKS6 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762633578, COSV62049898; called by muse, mutect2, varscan2
- ANO1 | c.1349T>C p.V450A | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100303652; called by muse, mutect2, varscan2
- ANO2 | c.2668G>T p.E890* (on ENST00000356134 / NM_001278597.3; = p.E894* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as rs1172533968, COSV100499642, COSV59045684; called by muse, mutect2, varscan2
- ANO6 | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV100262213; called by muse, mutect2, varscan2
- ANOS1 | c.1471G>T p.D491Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV52923704, COSV99390376; called by muse, mutect2, varscan2
- ANXA11 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs961003614, COSV55416756; called by muse, mutect2, varscan2
- ANXA3 | c.803A>G p.D268G | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs1483101853, COSV99363491; called by muse, mutect2, varscan2
- ANXA5 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396794753, COSV56640132; called by muse, mutect2, varscan2
- AOPEP | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs976191132, COSV52921376; called by muse, mutect2, varscan2
- AOX1 | c.2512C>T p.R838* | Nonsense Mutation (SNP) | VAF 21/72 reads (29%) | catalogued as rs961341488, COSV101021674; called by muse, mutect2, varscan2
- AP2A1 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100756104; called by muse, mutect2, varscan2
- AP3B1 | c.1173A>C p.E391D | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV99670596; called by muse, mutect2, varscan2
- AP5M1 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.402); catalogued as rs561546214, COSV99841000; called by muse, mutect2, varscan2
- APAF1 | c.1543G>A p.E515K (on ENST00000551964 / NM_181861.2; = p.E504K on NM_001160.3) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV100452258; called by muse, mutect2, varscan2
- APC | c.5582C>A p.S1861Y | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD961780, COSV104379185, COSV57328606; called by muse, mutect2, varscan2
- APC | c.6086C>T p.S2029F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99964923, COSV99964952; called by muse, mutect2, varscan2
- APCDD1 | c.944T>C p.F315S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100789894; called by muse, mutect2, varscan2
- APLP1 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 13/55 reads (24%) | catalogued as COSV99383497; called by muse, mutect2, varscan2
- APOA4 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 16/115 reads (14%) | catalogued as COSV100759242; called by muse, mutect2, varscan2
- APOB | c.12875C>T p.T4292I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs919234513, COSV99263356; called by muse, mutect2, varscan2
- APOB | c.9503C>A p.S3168* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as COSV99263361; called by muse, mutect2, varscan2
- APOB | c.5102G>T p.G1701V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99263366; called by muse, mutect2, varscan2
- APOBEC1 | c.517C>A p.L173M | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as COSV99980962; called by muse, mutect2, varscan2
- APOBEC3B | c.695A>G p.D232G | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as COSV100213640; called by muse, mutect2, varscan2
- APOBEC4 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.194); catalogued as rs753388975, COSV100426060; called by muse, mutect2, varscan2
- APOM | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776544922, COSV99276370; called by muse, mutect2, varscan2
- APOOL | c.127A>C p.I43L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV100920786; called by muse, mutect2, varscan2
- APOOL | c.525T>G p.I175M | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs766725192, COSV100920787; called by muse, mutect2, varscan2
- AQP8 | c.260+2T>C p.X87_splice | Splice Site (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99563680; called by muse, mutect2
- AQR | c.2719G>T p.E907* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as COSV50029523; called by muse, mutect2, varscan2
- AR | c.1763C>A p.A588D | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101017234, COSV65952771; called by muse, mutect2, varscan2
- AR | c.1852C>T p.R618W | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1218564193, CX116061, COSV65958933; called by muse, mutect2, varscan2
- ARAP2 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as COSV58291440; called by muse, mutect2, varscan2
- ARAP3 | c.1244G>A p.S415N | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99499273; called by muse, mutect2, varscan2
- AREG | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as rs1283640826; called by muse, mutect2, varscan2
- ARFGAP1 | c.866A>G p.D289G | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV100796612; called by muse, mutect2, varscan2
- ARFGAP2 | c.587A>C p.D196A | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as COSV100096021; called by muse, mutect2, varscan2
- ARGLU1 | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100639742; called by muse, mutect2, varscan2
- ARHGAP11A | c.2323T>G p.S775A | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.039); catalogued as COSV100276649; called by muse, mutect2
- ARHGAP11B | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368952454; called by muse, mutect2, varscan2
- ARHGAP20 | c.1595T>G p.F532C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV99503033; called by muse, mutect2, varscan2
- ARHGAP21 | c.3176A>C p.K1059T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100255707; called by muse, mutect2, varscan2
- ARHGAP30 | c.1858C>A p.L620M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100920128; called by muse, mutect2
- ARHGAP35 | c.3740T>G p.F1247C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68335680; called by muse, mutect2, varscan2
- ARHGAP36 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99357169; called by muse, mutect2, varscan2
- ARHGEF17 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs766975112, COSV99734815; called by muse, mutect2, varscan2
- ARHGEF26 | c.1823G>T p.R608I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV62844145; called by muse, mutect2, varscan2
- ARHGEF28 | c.2930T>G p.F977C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99708084; called by muse, mutect2, varscan2
- ARHGEF37 | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100381874, COSV61369840; called by muse, mutect2, varscan2
- ARHGEF6 | c.2237G>A p.R746K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV99166340; called by muse, varscan2
- ARHGEF9 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99491325; called by muse, mutect2, varscan2
- ARID2 | c.1141C>A p.L381I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as COSV100535319; called by muse, mutect2, varscan2
- ARID4A | c.2530G>T p.D844Y | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV100793975; called by muse, mutect2
- ARID5B | c.1726G>T p.E576* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV54420831; called by muse, varscan2
- ARL14 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as COSV100296386; called by muse, mutect2, varscan2
- ARL4A | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.997); catalogued as COSV100775878; called by muse, mutect2, varscan2
- ARL6 | c.381C>A p.F127L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.498); catalogued as COSV60117637, COSV60118364; called by mutect2, varscan2
- ARL8B | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56580537, COSV99848454; called by muse, mutect2, varscan2
- ARMC4 | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV99518162; called by muse, mutect2, varscan2
- ARMCX5 | c.798G>T p.K266N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV55767573, COSV99863289; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as COSV100771794; called by muse, mutect2, varscan2
- ARPP21 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.075); catalogued as COSV99490727; called by muse, mutect2, varscan2
- ARPP21 | c.1350G>T p.E450D | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.84); catalogued as COSV99490735; called by mutect2, varscan2
- ARPP21 | c.1499A>G p.Y500C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99490782; called by muse, mutect2, varscan2
- ARR3 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV99333478; called by muse, mutect2, varscan2
- ARSI | c.398A>G p.Q133R | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1209072405, COSV100155874; called by muse, mutect2, varscan2
- ARSL | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101140388; called by muse, mutect2, varscan2
- ASAP2 | c.1789G>A p.D597N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV99855692; called by muse, mutect2, varscan2
- ASB5 | c.661C>A p.L221I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV56668803; called by muse, mutect2, varscan2
- ASB5 | c.123C>A p.F41L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56672291; called by mutect2, varscan2
- ASCC3 | c.2477A>C p.K826T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100225140; called by muse, mutect2, varscan2
- ASH1L | c.1310A>C p.K437T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); catalogued as COSV100853087; called by mutect2, varscan2
- ASH2L | c.1474C>A p.L492I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV51699210; called by muse, mutect2, varscan2
- ASIC4 | c.1438C>A p.L480M (on ENST00000347842 / NM_182847.3; = p.L499M on NM_018674.6) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.076); catalogued as COSV61731269; called by muse, mutect2, varscan2
- ASMT | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 33/157 reads (21%) | catalogued as COSV101172401; called by muse, mutect2, varscan2
- ASNS | c.504G>T p.K168N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.072); catalogued as COSV51556639; called by muse, mutect2, varscan2
- ASPA | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV99279067; called by muse, mutect2, varscan2
- ASPM | c.3005G>A p.R1002H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs749600804, COSV99659426; called by mutect2, varscan2
- ASZ1 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99498014; called by muse, mutect2
- ASZ1 | c.584A>C p.K195T | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99497723; called by muse, mutect2
- ATAD2B | c.2868G>T p.E956D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99476898; called by muse, mutect2
- ATAD2B | c.2719T>G p.F907V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV99476900; called by muse, mutect2, varscan2
- ATAD2B | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99476901; called by muse, mutect2, varscan2
- ATCAY | c.201G>T p.E67D | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100008435; called by muse, mutect2, varscan2
- ATG2B | c.4661C>A p.S1554Y | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99951916; called by muse, mutect2, varscan2
- ATG4A | c.41T>G p.I14S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV100619539; called by muse, mutect2
- ATG4A | c.791C>A p.A264E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100619540; called by muse, mutect2
- ATG4C | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58608660; called by muse, mutect2, varscan2
- ATG4C | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100507799; called by muse, mutect2, varscan2
- ATIC | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as COSV99377403; called by muse, mutect2, varscan2
- ATM | c.2942G>A p.R981H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs755896387, COSV99587064; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATM | c.5788G>T p.D1930Y | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV99587067; called by mutect2, varscan2
- ATP10B | c.2966C>A p.A989D | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100514029; called by muse, mutect2, varscan2
- ATP10D | c.1747T>C p.Y583H | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV99905091; called by muse, mutect2
- ATP11C | c.2181G>T p.K727N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV59562556; called by muse, mutect2, varscan2
- ATP11C | c.1586G>T p.R529I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.21); catalogued as rs147128476, COSV100557301, COSV59568659, COSV59576357; called by muse, mutect2, varscan2
- ATP11C | c.1008G>T p.E336D | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV100557306; called by muse, mutect2, varscan2
- ATP12A | c.1417A>C p.K473Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99516938; called by muse, mutect2, varscan2
- ATP13A3 | c.1563T>G p.F521L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.14); catalogued as COSV99756131; called by mutect2, varscan2
- ATP13A4 | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.033); catalogued as COSV99793990; called by muse, mutect2, varscan2
- ATP13A4 | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV99793992; called by muse, mutect2, varscan2
- ATP13A5 | c.3486G>T p.K1162N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV99290512; called by muse, mutect2, varscan2
- ATP13A5 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60867945; called by muse, mutect2, varscan2
- ATP13A5 | c.384+1G>T p.X128_splice | Splice Site (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100664691; called by muse, mutect2, varscan2
- ATP1A3 | c.1297C>T p.R433C (on ENST00000545399 / NM_001256214.2; = p.R420C on NM_152296.5) | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1318364500, COSV57491023; called by muse, mutect2, varscan2
- ATP1B1 | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as COSV100891600; called by muse, mutect2, varscan2
- ATP1B4 | c.799G>A p.V267I (on ENST00000218008 / NM_001142447.3; = p.V263I on NM_012069.5) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.588); catalogued as COSV99486122; called by muse, mutect2, varscan2
- ATP2A3 | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1483761301, COSV99988738; called by muse, mutect2, varscan2
- ATP4A | c.950T>G p.F317C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99382071; called by muse, mutect2, varscan2
- ATP6V1C1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV101214817; called by muse, mutect2, varscan2
- ATP7A | c.2957G>A p.R986Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); catalogued as rs781995242, CM078711, COSV58442198; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8A1 | c.2323C>T p.R775W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867059514, COSV100044799; called by muse, mutect2, varscan2
- ATP8A1 | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100044804; called by muse, mutect2
- ATP8A2 | c.1363G>T p.E455* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99679800; called by muse, mutect2, varscan2
- ATP8B4 | c.2861A>C p.K954T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV52719786; called by muse, mutect2, varscan2
- ATP8B4 | c.2080G>T p.D694Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99463415, COSV99467118; called by muse, mutect2, varscan2
- ATR | c.7591C>A p.L2531I | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.383); catalogued as COSV100637643; called by muse, mutect2, varscan2
- ATR | c.953T>C p.L318S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100637644, COSV63384728; called by muse, mutect2, varscan2
- ATRX | c.4564G>T p.E1522* | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as COSV64874759; called by muse, mutect2, varscan2
- ATRX | c.2714G>T p.R905I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV100969953; called by muse, mutect2, varscan2
- ATRX | c.2418G>T p.K806N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV64882427; called by muse, varscan2
- ATRX | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV64886569; called by muse, varscan2
- ATRX | c.1875G>T p.E625D | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.97); catalogued as COSV100969955; called by muse, mutect2, varscan2
- ATXN3L | c.863A>G p.E288G | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV101019295; called by muse, mutect2, varscan2
- AURKC | c.641G>A p.R214K (on ENST00000302804 / NM_001015878.2; = p.R180K on NM_003160.3) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100248697; called by muse, mutect2, varscan2
- AVPR1A | c.1239C>A p.F413L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.442); catalogued as rs144329263; called by muse, mutect2, varscan2
- B2M | c.122A>T p.N41I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100837544, COSV62564782; called by muse, mutect2, varscan2
- BAP1 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs1559589762, COSV56237334, COSV99963329; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BARD1 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV53613980, COSV99637696, COSV99637785; called by muse, mutect2, varscan2
- BARD1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs730881412, COSV99637789, COSV99638842; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ2B | c.5552T>G p.F1851C | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100600330; called by muse, mutect2, varscan2
- BBS10 | c.653T>G p.F218C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99674424; called by muse, mutect2
- BBS2 | c.1912A>C p.K638Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.436); catalogued as COSV99802047; called by muse, mutect2, varscan2
- BBS7 | c.2045T>G p.F682C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV99144800; called by muse, mutect2, varscan2
- BBS7 | c.1001T>G p.I334S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV99144801; called by muse, mutect2, varscan2
- BBS9 | c.1930G>T p.E644* (on ENST00000242067 / NM_001348036.1; = p.E604* on NM_014451.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as COSV54178324; called by muse, mutect2, varscan2
- BCHE | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV100012056; called by muse, mutect2, varscan2
- BCL2L14 | c.621A>C p.Q207H | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV99844865; called by muse, mutect2, varscan2
- BCL6 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs1466914215, COSV51651028; called by muse, mutect2, varscan2
- BCL6B | c.391A>G p.I131V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.127); catalogued as COSV99546399; called by muse, mutect2, varscan2
- BCL9L | c.3980C>T p.S1327L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1349109265, COSV99418482; called by muse, mutect2, varscan2
- BCLAF1 | c.2551G>A p.D851N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99219212; called by muse, mutect2
- BCLAF1 | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.947); catalogued as rs1487882129, COSV50361469; called by muse, mutect2, varscan2
- BCLAF1 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs1472581269, COSV100786368; called by muse, mutect2, varscan2
- BDH1 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as rs771764181, COSV64019147; called by muse, mutect2, varscan2
- BEND2 | c.2056G>A p.A686T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs778717370, COSV66215972, COSV66217169; called by mutect2, varscan2
- BEND6 | c.813A>T p.K271N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.179); catalogued as COSV100876739; called by muse, varscan2
- BEND7 | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100346344; called by muse, mutect2, varscan2
- BFSP1 | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763099974, COSV64900602; called by muse, mutect2, varscan2
- BGN | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.464); catalogued as COSV100525175, COSV59035987; called by muse, mutect2, varscan2
- BICC1 | c.2851C>A p.L951M | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100874690; called by muse, mutect2, varscan2
- BLM | c.819G>T p.K273N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV100756863, COSV100756893; called by muse, mutect2, varscan2
- BMP15 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV99399156; called by muse, varscan2
- BMP15 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs367885992, COSV53140423; called by muse, mutect2, varscan2
- BMPER | c.462G>T p.E154D | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99778800; called by muse, mutect2, varscan2
- BMX | c.245T>G p.I82S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100564274; called by muse, mutect2, varscan2
- BNC2 | c.2883C>A p.D961E | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101035213; called by muse, mutect2, varscan2
- BNIP1 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as rs748038701, COSV51569932; called by mutect2, varscan2
- BOLL | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV99986832, COSV99987029; called by muse, mutect2, varscan2
- BPI | c.573A>C p.K191N (on ENST00000262865; = p.K187N on NM_001725.3) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.194); catalogued as COSV99480370; called by muse, mutect2, varscan2
- BPTF | c.3436G>A p.D1146N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs201720584; called by mutect2, varscan2
- BPTF | c.6707A>C p.N2236T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100073922; called by muse, mutect2, varscan2
- BRAP | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as COSV100553939; called by muse, mutect2, varscan2
- BRD4 | c.1868A>G p.N623S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV104373462; called by muse, mutect2
- BRD8 | c.447G>T p.K149N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1217534460, COSV99136562; called by muse, mutect2, varscan2
- BRD9 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as rs756703738, COSV60244587, COSV60247591; called by muse, mutect2, varscan2
- BRIP1 | c.3188C>T p.S1063L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.031); catalogued as rs575998972, COSV99369164, COSV99370889; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRIP1 | c.1141-1G>A p.X381_splice | Splice Site (SNP) | VAF 5/24 reads (21%) | catalogued as COSV51995591, COSV99369166; called by muse, mutect2, varscan2
- BRIP1 | c.479G>T p.R160I | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1330277587, COSV51994294; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD3 | c.4379C>A p.S1460Y | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.271); catalogued as COSV100955613; called by muse, mutect2, varscan2
- BRWD3 | c.3976C>T p.R1326* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as rs866592729, COSV64746272; called by muse, mutect2, varscan2
- BRWD3 | c.1939C>A p.L647I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV64744132, COSV64753055; called by muse, mutect2, varscan2
- BRWD3 | c.1355C>A p.S452Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100955616; called by muse, mutect2, varscan2
- BTBD11 | c.2996T>G p.L999R (on ENST00000280758 / NM_001018072.2; = p.L536R on NM_001017523.2) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99774654; called by muse, mutect2, varscan2
- BTBD7 | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as rs1198567556, COSV100597941, COSV58283311; called by muse, mutect2, varscan2
- BTBD8 | c.1099C>A p.L367I | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.283); catalogued as COSV100730091; called by muse, mutect2, varscan2
- BTBD9 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs757813575, COSV100020862; called by muse, mutect2, varscan2
- BTN1A1 | c.971C>A p.S324Y | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV55066892, COSV99764145; called by muse, mutect2, varscan2
- BTN2A1 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 28/124 reads (23%) | catalogued as COSV100438360; called by muse, mutect2, varscan2
- BUD23 | c.131T>C p.L44S | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV99736257; called by muse, mutect2, varscan2
- BVES | c.331C>A p.L111I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.804); catalogued as rs760966564, COSV58947103; called by muse, mutect2, varscan2
- C10orf90 | c.1459C>A p.L487I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as rs140833099; called by muse, mutect2, varscan2
- C10orf90 | c.69A>C p.K23N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV99503005; called by muse, mutect2, varscan2
- C11orf65 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101262710; called by muse, mutect2, varscan2
- C11orf65 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV101262711; called by muse, mutect2, varscan2
- C12orf40 | c.1209A>C p.E403D | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as COSV100209605; called by muse, varscan2
- C12orf50 | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 30/109 reads (28%) | catalogued as rs200677856, COSV53893431, COSV53897104; called by muse, mutect2, varscan2
- C14orf28 | c.186C>A p.F62L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV57332835, COSV57334153; called by muse, mutect2, varscan2
- C16orf46 | c.688A>T p.K230* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as COSV100215079; called by muse, mutect2, varscan2
- C19orf47 | c.702A>C p.K234N | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as COSV100775015; called by muse, mutect2, varscan2
- C1GALT1 | c.265A>C p.I89L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.323); catalogued as COSV99777488; called by muse, mutect2, varscan2
- C1QTNF7 | c.814C>A p.L272I | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99764972; called by muse, mutect2
- C1orf105 | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV100877913, COSV100877981; called by muse, mutect2, varscan2
- C1orf105 | c.445A>G p.T149A | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as COSV100877914; called by muse, mutect2, varscan2
- C1orf112 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752651784, COSV99609343; called by muse, mutect2, varscan2
- C1orf112 | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.086); catalogued as COSV99609346; called by muse, varscan2
- C1orf141 | c.1183G>T p.E395* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as rs868495930, COSV100924271; called by muse, mutect2, varscan2
- C1orf52 | c.305C>A p.S102* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99640877; called by muse, mutect2, varscan2
- C20orf194 | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | catalogued as COSV52691778; called by muse, mutect2, varscan2
- C2CD3 | c.2121C>A p.F707L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as COSV100486207, COSV100487314; called by muse, mutect2, varscan2
- C2CD6 | c.1864G>T p.G622* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV99631801; called by muse, mutect2, varscan2
- C2orf76 | c.356A>C p.K119T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100601579; called by muse, mutect2
- C2orf78 | c.1108T>G p.S370A | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.022); catalogued as COSV101280893; called by muse, mutect2, varscan2
- C2orf78 | c.1649C>A p.S550Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV101280894; called by muse, mutect2, varscan2
- C2orf80 | c.353C>A p.S118Y | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.648); catalogued as COSV100378266, COSV58015998; called by muse, mutect2, varscan2
- C3orf14 | c.279A>C p.E93D | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV99223654; called by mutect2, varscan2
- C3orf52 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs746731235, COSV53494867; called by muse, mutect2, varscan2
- C5orf38 | c.410G>T p.R137I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs779809202, COSV57409721; called by muse, mutect2, varscan2
- C6orf118 | c.1247C>A p.T416N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.121); catalogued as COSV100023989; called by muse, mutect2, varscan2
- C6orf47 | c.260G>T p.R87I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); catalogued as COSV100788960; called by muse, mutect2
- C7 | c.373A>G p.R125G | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.261); catalogued as COSV100495337; called by muse, mutect2, varscan2
- C8A | c.1343G>T p.R448M | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100776429; called by muse, mutect2, varscan2
- C8A | c.1436A>C p.K479T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100776430; called by muse, mutect2, varscan2
- C9orf131 | c.1463A>C p.Q488P | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100397906; called by muse, mutect2, varscan2
- C9orf131 | c.2242C>A p.L748I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV100397908, COSV56609609; called by muse, mutect2, varscan2
- C9orf153 | c.94A>G p.N32D | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV100188600; called by muse, mutect2, varscan2
- CA1 | c.255C>A p.F85L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99809983; called by muse, mutect2, varscan2
- CABIN1 | c.1245G>T p.M415I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99572637; called by muse, mutect2, varscan2
- CACNA1A | c.1049T>G p.F350C | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100800677; called by muse, mutect2, varscan2
- CACNA1C | c.2993G>A p.R998Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs755609118, COSV59738272; called by muse, mutect2, varscan2
- CACNA1D | c.1508G>A p.R503Q (on ENST00000350061 / NM_001128840.3; = p.R523Q on NM_000720.4) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs941177114, COSV99856473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs373195246; called by muse, mutect2, varscan2
- CACNA1E | c.1538T>G p.F513C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100701264; called by muse, mutect2, varscan2
- CACNA1E | c.2234C>T p.S745L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.086); catalogued as rs776757923, COSV62406537; called by muse, mutect2, varscan2
- CACNA1I | c.2545G>A p.G849S | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100359074; called by muse, mutect2, varscan2
- CACNA1I | c.2849G>A p.R950Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs370082731; called by muse, mutect2, varscan2
- CACNA2D1 | c.2047T>G p.F683V (on ENST00000356253 / NM_001366867.1; = p.F671V on NM_000722.4) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV100665677; called by muse, mutect2, varscan2
- CACNA2D4 | c.580C>A p.H194N | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99764994; called by muse, mutect2, varscan2
- CACNB3 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99974633; called by muse, mutect2, varscan2
- CACNB3 | c.1173G>T p.E391D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV56401322, COSV99974636; called by muse, mutect2, varscan2
- CACNB4 | c.1291T>G p.S431A | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); catalogued as COSV99137728; called by muse, varscan2
- CADM1 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs758008656, COSV59002787; called by muse, mutect2, varscan2
- CADM1 | c.266T>G p.F89C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV100522076; called by muse, mutect2
- CADM2 | c.884G>A p.R295Q (on ENST00000407528 / NM_001167674.2; = p.R297Q on NM_153184.4) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as rs745873421, COSV67364782; called by muse, mutect2, varscan2
- CADPS | c.3620C>A p.S1207Y | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99335682; called by muse, mutect2, varscan2
- CADPS | c.2365C>A p.L789M | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV99335685; called by muse, mutect2, varscan2
- CAGE1 | c.1847A>C p.K616T (on ENST00000512086; = p.K480T on NM_205864.3) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV99699349; called by muse, mutect2, varscan2
- CALB1 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as COSV99617885; called by muse, mutect2, varscan2
- CALCR | c.420G>T p.E140D | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV100810374; called by muse, mutect2, varscan2
- CALCRL | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV101130839; called by muse, mutect2
- CALR3 | c.80T>G p.F27C | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99522040; called by muse, mutect2, varscan2
- CAMK2B | c.1041G>T p.K347N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV99322709; called by muse, mutect2, varscan2
- CAMK2B | c.843G>T p.M281I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.083); catalogued as COSV99322710; called by mutect2, varscan2
- CAMTA2 | c.1453G>T p.G485* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100772320; called by muse, mutect2, varscan2
- CAND2 | c.3609C>A p.F1203L (on ENST00000456430 / NM_001162499.2; = p.F1086L on NM_012298.3) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.139); catalogued as COSV55994094; called by muse, mutect2, varscan2
- CAPN3 | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as COSV58820476; called by muse, mutect2, varscan2
- CARD6 | c.1783A>C p.I595L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV99620116; called by muse, mutect2, varscan2
- CARF | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs577808416, COSV100247472; called by muse, mutect2, varscan2
- CARMIL2 | c.1688A>G p.K563R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.13); catalogued as COSV100575932; called by muse, mutect2, varscan2
- CARNMT1 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs761039862, COSV100961056; called by muse, mutect2, varscan2
- CASP8AP2 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99386726; called by muse, mutect2
- CASP8AP2 | c.5812T>G p.L1938V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52746201; called by muse, mutect2, varscan2
- CASQ2 | c.623C>A p.S208Y | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs1289357362, COSV99796993; called by muse, mutect2, varscan2
- CASR | c.2914G>T p.E972* (on ENST00000490131; = p.E1049* on NM_000388.4) | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | catalogued as COSV99948410; called by muse, mutect2
- CASS4 | c.632G>A p.S211N | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV100824518; called by muse, mutect2
- CAST | c.393G>T p.K131N (on ENST00000341926; = p.K214N on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV100352134; called by muse, mutect2, varscan2
- CATSPER4 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756980204, COSV58793449; called by muse, mutect2, varscan2
- CATSPERB | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as rs779893104, COSV56422429, COSV99831126; called by muse, mutect2, varscan2
- CATSPERG | c.2791A>G p.I931V | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.103); catalogued as COSV99286008; called by muse, mutect2, varscan2
- CATSPERG | c.2860G>A p.G954R | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148888831, COSV99286012; called by muse, mutect2, varscan2
- CAVIN3 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1427872531; called by muse, mutect2
- CBFA2T2 | c.729G>T p.E243D | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1230077240, COSV60074720; called by muse, mutect2, varscan2
- CBFA2T2 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs146788442; called by muse, mutect2, varscan2
- CBLB | c.1361A>G p.D454G | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.248); catalogued as COSV99912579; called by muse, mutect2, varscan2
- CBLL2 | c.41A>C p.N14T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV100081434, COSV100081535; called by muse, mutect2, varscan2
- CBLN3 | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs760763185, COSV52160248; called by muse, mutect2, varscan2
- CCDC102B | c.1492G>T p.E498* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100102014, COSV60135503, COSV60137000; called by muse, mutect2
- CCDC122 | c.653A>C p.K218T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.319); catalogued as COSV99865790; called by muse, varscan2
- CCDC125 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV101143457; called by muse, mutect2, varscan2
- CCDC144A | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.047); catalogued as COSV100138298; called by muse, varscan2
- CCDC144A | c.1895C>A p.S632Y | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100138302; called by muse, mutect2, varscan2
- CCDC15 | c.2134G>T p.E712* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as rs1463942505, COSV100776889; called by muse, mutect2, varscan2
- CCDC15 | c.2554G>T p.E852* | Nonsense Mutation (SNP) | VAF 3/17 reads (18%) | catalogued as COSV100776890; called by muse, mutect2
- CCDC150 | c.1475G>T p.R492I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as COSV99776461; called by muse, mutect2
- CCDC151 | c.1788G>T p.*596Yext*57 | Nonstop Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100710439; called by muse, mutect2, varscan2
- CCDC158 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as rs372653725; called by mutect2, varscan2
- CCDC158 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 15/75 reads (20%) | catalogued as COSV101187139; called by muse, mutect2, varscan2
- CCDC160 | c.14G>T p.R5I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs947108162, COSV100892084; called by muse, mutect2, varscan2
- CCDC160 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100892085; called by muse, mutect2, varscan2
- CCDC171 | c.396A>C p.K132N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99899775; called by muse, mutect2, varscan2
- CCDC171 | c.2744A>C p.K915T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99899778; called by muse, mutect2, varscan2
- CCDC174 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV57980779; called by muse, mutect2, varscan2
- CCDC18 | c.3743C>T p.S1248F (on ENST00000343253 / NM_001306076.1; = p.S1249F on NM_206886.4) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100159194; called by muse, mutect2
- CCDC181 | c.1194A>C p.E398D | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV100890232; called by muse, mutect2, varscan2
- CCDC181 | c.810A>C p.E270D | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV100890233; called by mutect2, varscan2
- CCDC181 | c.639G>T p.K213N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV63158486; called by muse, mutect2, varscan2
- CCDC184 | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.922); catalogued as COSV100343906; called by muse, mutect2, varscan2
- CCDC191 | c.2322T>G p.H774Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99877867; called by muse, mutect2, varscan2
- CCDC30 | c.1715G>T p.R572I (on ENST00000340612; = p.R529I on NM_001080850.3) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs768076529, COSV100500992, COSV59607215; called by mutect2, varscan2
- CCDC38 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs762838749, COSV60184165, COSV60185012; called by muse, mutect2, varscan2
- CCDC39 | c.2198A>C p.K733T | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV99867018; called by muse, mutect2, varscan2
- CCDC39 | c.2080G>A p.A694T | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs769886847, COSV99867021; called by muse, mutect2, varscan2
- CCDC39 | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 16/89 reads (18%) | catalogued as rs1472519086, COSV56487128; called by muse, mutect2, varscan2
- CCDC60 | c.1003T>G p.S335A | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.053); catalogued as COSV100554572; called by muse, mutect2
- CCDC63 | c.1104G>T p.Q368H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100370170; called by muse, mutect2, varscan2
- CCDC63 | c.1625A>C p.E542A | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.277); catalogued as COSV99960571; called by muse, mutect2, varscan2
- CCDC68 | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as COSV100491586, COSV61603613; called by muse, mutect2, varscan2
- CCDC73 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs904230248, COSV58802407; called by muse, mutect2, varscan2
- CCDC85A | c.876G>T p.Q292H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.656); catalogued as COSV101339359; called by muse, mutect2, varscan2
- CCDC85A | c.1457C>A p.S486Y | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.365); catalogued as COSV68150281; called by muse, mutect2, varscan2
- CCDC88A | c.3865T>G p.F1289V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV99709725; called by muse, mutect2, varscan2
- CCDC88C | c.2867A>C p.K956T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV101105064; called by muse, mutect2, varscan2
- CCDC89 | c.711G>T p.K237N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV100320803; called by muse, mutect2
- CCDC9 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs539655267, COSV55721311; called by muse, mutect2, varscan2
- CCDC91 | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV101174930, COSV67125986; called by muse, mutect2, varscan2
- CCER1 | c.1128G>T p.E376D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as rs528219668, COSV62646491, COSV62648654; called by muse, mutect2
- CCL24 | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56116306; called by muse, mutect2, varscan2
- CCM2 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV99347473; called by muse, mutect2, varscan2
- CCNA1 | c.818A>G p.D273G | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1041438719, COSV99714263; called by muse, mutect2, varscan2
- CCNA1 | c.1143A>C p.K381N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as COSV99714266; called by muse, mutect2, varscan2
- CCNB1IP1 | c.360G>T p.Q120H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.407); catalogued as COSV100738483; called by muse, mutect2, varscan2
- CCNB3 | c.1773G>T p.K591N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1200046820, COSV99328390; called by muse, varscan2
- CCNC | c.420C>A p.F140L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58334062; called by muse, mutect2, varscan2
- CCND2 | c.198C>A p.V66= | Splice Region (SNP) | VAF 13/52 reads (25%) | catalogued as rs780412072, COSV99714000; called by muse, mutect2, varscan2
- CCNE1 | c.516C>A p.F172L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV52903510, COSV52904939; called by muse, mutect2, varscan2
- CCNL2 | c.150G>T p.E50D | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.428); catalogued as COSV61224065; called by muse, mutect2, varscan2
- CCSER1 | c.325A>G p.I109V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs778993763, COSV100387683; called by muse, mutect2, varscan2
- CCSER2 | c.1021A>C p.N341H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV99825394; called by muse, mutect2, varscan2
- CCT4 | c.437A>C p.E146A | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV101075045; called by muse, mutect2, varscan2
- CCZ1 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100382676; called by muse, mutect2, varscan2
- CCZ1B | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 15/98 reads (15%) | catalogued as COSV100367710; called by muse, mutect2, varscan2
- CD163 | c.3264G>T p.E1088D | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.581); catalogued as rs1328891280, COSV63130486; called by muse, mutect2, varscan2
- CD163 | c.2468C>A p.S823Y | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100775612; called by muse, mutect2
- CD163 | c.2132T>C p.V711A | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100775613; called by muse, mutect2, varscan2
- CD4 | c.611T>A p.F204Y | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99163686; called by muse, mutect2, varscan2
- CD44 | c.1393C>A p.H465N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV99555396; called by muse, mutect2, varscan2
- CD5L | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs146902396, COSV63822495; called by muse, mutect2, varscan2
- CD82 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs370975589, COSV57035345; called by muse, mutect2, varscan2
- CDA | c.78G>T p.K26N | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66752043; called by muse, mutect2, varscan2
- CDC37L1 | c.590T>G p.L197R | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101116461; called by muse, mutect2, varscan2
- CDC42BPA | c.3472G>T p.D1158Y (on ENST00000334218 / NM_001366019.2; = p.D1145Y on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100503599; called by muse, mutect2, varscan2
- CDC7 | c.1048A>G p.T350A | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.063); catalogued as rs1453101216, COSV99319526; called by muse, mutect2, varscan2
- CDH10 | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100049917, COSV100050168; called by muse, varscan2
- CDH11 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51753330, COSV99217031; called by muse, mutect2, varscan2
- CDH11 | c.146A>G p.Q49R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as COSV99217036; called by muse, mutect2, varscan2
- CDH12 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 19/107 reads (18%) | catalogued as COSV66396285, COSV66415403; called by muse, mutect2, varscan2
- CDH17 | c.569C>A p.S190Y | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99216913; called by muse, mutect2, varscan2
- CDH17 | c.48T>G p.Y16* | Nonsense Mutation (SNP) | VAF 14/25 reads (56%) | catalogued as COSV99216914; called by muse, mutect2, varscan2
- CDH18 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 21/88 reads (24%) | catalogued as COSV56975147, COSV99931852; called by muse, mutect2, varscan2
- CDH19 | c.1660G>A p.D554N | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1489452078, COSV100050775, COSV50958471; called by muse, mutect2, varscan2
- CDH19 | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV50979350, COSV50985804; called by muse, mutect2, varscan2
- CDH19 | c.16C>A p.L6M | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.365); catalogued as COSV100050777; called by muse, mutect2, varscan2
- CDH26 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758854327, COSV99721690; called by muse, mutect2, varscan2
- CDH26 | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); catalogued as COSV99721692; called by muse, mutect2, varscan2
- CDH4 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.092); catalogued as COSV100848401; called by muse, mutect2, varscan2
- CDH6 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as rs769326582, COSV54067130; called by muse, mutect2, varscan2
- CDH6 | c.1693C>A p.L565I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as COSV99417950; called by muse, mutect2, varscan2
- CDH7 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59883306; called by muse, mutect2, varscan2
- CDH7 | c.1933G>T p.D645Y | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100541324; called by muse, mutect2, varscan2
- CDH8 | c.1956A>C p.L652F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV100179448; called by muse, varscan2
- CDH9 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99141403; called by muse, mutect2, varscan2
- CDHR3 | c.946C>A p.L316I | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.741); catalogued as COSV100487924; called by muse, mutect2, varscan2
- CDKL3 | c.1376G>T p.R459I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV99527510; called by muse, mutect2, varscan2
- CDKN2AIPNL | c.126A>C p.E42D | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV101212817; called by muse, mutect2, varscan2
- CDON | c.2375A>C p.K792T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99700509; called by muse, mutect2
- CDON | c.598C>A p.Q200K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV99700518; called by mutect2, varscan2
- CDON | c.10G>T p.D4Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV99700522; called by muse, mutect2, varscan2
- CDS1 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV99880356; called by muse, mutect2, varscan2
- CEACAM18 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as COSV101140129; called by muse, mutect2, varscan2
- CELA2B | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs1308898782, COSV100423590, COSV61600879; called by muse, mutect2, varscan2
- CELSR2 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs781644562, COSV99602965, COSV99603988; called by mutect2, varscan2
- CEMIP | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54989831, COSV99585960; called by muse, mutect2, varscan2
- CENPE | c.4037C>A p.S1346Y | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.459); catalogued as COSV99476866; called by muse, mutect2, varscan2
- CENPF | c.6196G>T p.E2066* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as rs1558186264, COSV100871474; called by muse, mutect2, varscan2
- CENPI | c.1109C>A p.S370Y | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV99514986; called by muse, mutect2, varscan2
- CENPM | c.149A>C p.K50T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.026); catalogued as COSV99317764; called by muse, mutect2, varscan2
- CENPQ | c.682A>T p.I228F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV100225603; called by muse, mutect2, varscan2
- CEP112 | c.1342A>C p.T448P | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.693); catalogued as COSV101210493; called by muse, mutect2, varscan2
- CEP120 | c.2851G>T p.E951* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV100070748; called by muse, mutect2, varscan2
- CEP126 | c.1361C>T p.T454I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.209); catalogued as COSV99680528; called by muse, mutect2, varscan2
- CEP152 | c.4272G>T p.E1424D (on ENST00000380950 / NM_001194998.2; = p.E1368D on NM_014985.4) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.905); catalogued as COSV100358450; called by muse, mutect2, varscan2
- CEP152 | c.2995G>T p.E999* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as COSV100358454; called by muse, mutect2, varscan2
- CEP152 | c.1874A>C p.K625T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs1341694907, COSV100358456; called by muse, varscan2
- CEP152 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as COSV100358459; called by muse, mutect2
- CEP162 | c.3490T>G p.F1164V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100002339; called by muse, mutect2, varscan2
- CEP170 | c.358C>A p.Q120K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV100316328; called by muse, mutect2, varscan2
- CEP192 | c.5233G>A p.E1745K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1333082308, COSV58062644; called by muse, mutect2, varscan2
- CEP290 | c.3907G>T p.E1303* | Nonsense Mutation (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100467697; called by muse, mutect2, varscan2
- CEP290 | c.3257C>T p.S1086L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as rs760934388, COSV58357676; called by muse, mutect2, varscan2
- CEP290 | c.2835G>T p.K945N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100467703; called by muse, mutect2, varscan2
- CEP55 | c.322A>C p.T108P | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV101016831; called by muse, mutect2, varscan2
- CEP83 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100352617; called by muse, mutect2, varscan2
- CEP85L | c.2154A>C p.E718D | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100874028; called by muse, mutect2, varscan2
- CEP95 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs782641519, COSV101616286; called by muse, mutect2, varscan2
- CEP97 | c.2076G>T p.E692D | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV59123261; called by muse, mutect2, varscan2
- CEPT1 | c.968T>G p.F323C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100718512; called by muse, mutect2
- CERS6 | c.917T>G p.L306R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.449); catalogued as COSV99986439; called by muse, mutect2, varscan2
- CES3 | c.1095G>T p.M365I | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs750835792, COSV100309779, COSV57595032; called by muse, mutect2, varscan2
- CES5A | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV51863276; called by muse, mutect2, varscan2
- CFAP161 | c.321A>C p.L107F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as COSV99715362; called by muse, mutect2, varscan2
- CFAP46 | c.7245C>A p.F2415L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.274); catalogued as COSV99583853; called by muse, mutect2, varscan2
- CFAP46 | c.6583G>A p.A2195T | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.099); catalogued as COSV99583858; called by muse, mutect2, varscan2
- CFAP47 | c.5062G>T p.E1688* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100544864, COSV57974966; called by muse, mutect2, varscan2
- CFAP54 | c.5050G>T p.E1684* | Nonsense Mutation (SNP) | VAF 19/87 reads (22%) | catalogued as COSV100732908; called by muse, mutect2, varscan2
- CFAP54 | c.6545G>T p.R2182I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV61574975; called by muse, mutect2
- CFAP58 | c.1298A>C p.K433T | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100458729, COSV57211279; called by muse, mutect2, varscan2
- CFAP91 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs765608012, COSV99846789; called by muse, mutect2, varscan2
- CFAP94 | c.1104C>A p.F368L (on ENST00000320267 / NM_001352064.2; = p.F374L on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.023); catalogued as rs1013340991, COSV57230587; called by muse, varscan2
- CFAP94 | c.609A>C p.E203D (on ENST00000320267 / NM_001352064.2; = p.E209D on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100208880; called by muse, mutect2, varscan2
- CFAP94 | c.292T>G p.Y98D (on ENST00000320267 / NM_001352064.2; = p.Y104D on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100208882; called by muse, mutect2, varscan2
- CFH | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV66406684, COSV66414279; called by muse, mutect2, varscan2
- CFLAR | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1382779113, COSV100009050; called by muse, mutect2, varscan2
- CGNL1 | c.2665G>T p.E889* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99847369; called by muse, mutect2, varscan2
- CHD2 | c.3215G>A p.R1072Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101244657; called by muse, mutect2, varscan2
- CHD6 | c.5156C>A p.S1719Y | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as COSV100950516, COSV100950942; called by muse, mutect2
- CHD7 | c.5049C>T p.S1683= | Splice Region (SNP) | VAF 5/27 reads (19%) | catalogued as rs529369619, COSV71112918; called by mutect2, varscan2
- CHD7 | c.6861C>A p.F2287L | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as COSV101417968; called by muse, mutect2, varscan2
- CHD8 | c.3894C>A p.F1298L (on ENST00000646647 / NM_001170629.2; = p.F1019L on NM_020920.4) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100783784; called by muse, mutect2, varscan2
- CHD8 | c.2629G>T p.E877* (on ENST00000646647 / NM_001170629.2; = p.E598* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as rs1555315678, COSV101303029; called by muse, mutect2, varscan2
- CHD8 | c.2004C>A p.F668L (on ENST00000646647 / NM_001170629.2; = p.F389L on NM_020920.4) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs1445246220, COSV67869656; called by mutect2, varscan2
- CHD9 | c.2276T>G p.F759C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV101271863; called by muse, mutect2
- CHD9 | c.4807C>T p.R1603* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as rs1353837906, COSV99528663; called by muse, mutect2, varscan2
- CHERP | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52225429, COSV99550585; called by muse, mutect2, varscan2
- CHID1 | c.118T>G p.F40V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100059345, COSV60259406; called by muse, mutect2, varscan2
- CHL1 | c.60A>C p.K20N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV99849953; called by muse, mutect2, varscan2
- CHMP3 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV55685319, COSV99806495; called by muse, mutect2, varscan2
- CHPF2 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.876); catalogued as rs370642310; called by muse, varscan2
- CHRM3 | c.860C>A p.S287Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.806); catalogued as COSV99697378; called by muse, mutect2, varscan2
- CHRNA3 | c.692T>C p.I231T | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100467793; called by muse, mutect2, varscan2
- CHRNA4 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); catalogued as rs1247664860, COSV64719141; called by muse, mutect2, varscan2
- CHST8 | c.759G>T p.K253N | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99380586; called by muse, mutect2, varscan2
- CHSY3 | c.2304C>A p.F768L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV100518419; called by muse, mutect2
- CILP | c.2791G>A p.E931K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as rs780209937, COSV56026633; called by muse, mutect2, varscan2
- CILP | c.2292C>A p.F764L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV99972720; called by muse, mutect2, varscan2
- CILP2 | c.1840G>T p.D614Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99364279; called by muse, mutect2, varscan2
- CKAP5 | c.1954G>T p.E652* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100370337; called by muse, mutect2, varscan2
- CLCA1 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.376); catalogued as COSV99321864; called by muse, mutect2, varscan2
- CLCA2 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100991319; called by muse, mutect2, varscan2
- CLCN1 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs368280521, CX942107; called by muse, mutect2, varscan2
- CLCN5 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1373322324, COSV100259774; called by muse, mutect2, varscan2
- CLDN22 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as COSV100032764; called by muse, mutect2, varscan2
- CLDND1 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV57858931; called by muse, mutect2
- CLEC16A | c.1829T>G p.F610C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101277792; called by muse, mutect2, varscan2
- CLEC4A | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as rs773649897, COSV57561538; called by muse, mutect2, varscan2
- CLEC4F | c.466C>A p.L156I | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV99713505; called by muse, mutect2, varscan2
- CLGN | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs376735755; called by muse, mutect2, varscan2
- CLIC2 | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100425400; called by muse, mutect2, varscan2
- CLIC2 | c.38A>G p.E13G | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV100425403, COSV58937797; called by muse, mutect2, varscan2
- CLIP2 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs376110415, COSV56285671; called by muse, mutect2, varscan2
- CLPTM1L | c.835T>G p.F279V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100306767; called by muse, mutect2, varscan2
- CLSPN | c.3487G>T p.E1163* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as COSV99230227; called by muse, mutect2
- CLSTN2 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.353); catalogued as rs370992311, COSV71720647; called by muse, mutect2
- CLTC | c.2767C>T p.R923C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs962752209, COSV99291639; called by muse, mutect2, varscan2
- CLTRN | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100982183; called by muse, mutect2, varscan2
- CMTM2 | c.332A>G p.H111R | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV99216360; called by muse, mutect2
- CMTR2 | c.1570G>T p.E524* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100578961; called by muse, mutect2
- CMYA5 | c.2439G>T p.K813N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV101483798; called by mutect2, varscan2
- CMYA5 | c.2905G>T p.E969* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV101483799; called by muse, mutect2, varscan2
- CMYA5 | c.12066C>A p.F4022L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101405639; called by muse, mutect2, varscan2
- CNGA2 | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV100323364; called by mutect2, varscan2
- CNGA2 | c.1603C>T p.R535* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV61703983; called by muse, mutect2, varscan2
- CNGB3 | c.1882C>A p.L628I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100181115, COSV60695355; called by muse, mutect2, varscan2
- CNKSR2 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV54254348, COSV54259435; called by muse, mutect2, varscan2
- CNKSR2 | c.266C>A p.S89Y | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99667233; called by muse, mutect2, varscan2
- CNKSR2 | c.825G>T p.L275F | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99667236; called by muse, mutect2, varscan2
- CNKSR2 | c.1846G>T p.G616* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV99667238; called by muse, varscan2
- CNKSR2 | c.2023G>T p.E675* | Nonsense Mutation (SNP) | VAF 27/130 reads (21%) | catalogued as COSV99667240; called by muse, mutect2, varscan2
- CNNM2 | c.2351C>A p.S784Y | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs1218026306, COSV100881797, COSV64001480; called by muse, mutect2, varscan2
- CNOT1 | c.5441G>A p.R1814Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV55319793; called by muse, mutect2, varscan2
- CNOT11 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as COSV56820590; called by muse, mutect2, varscan2
- CNOT6L | c.53G>T p.R18I (on ENST00000504123 / NM_001286790.2; = p.R13I on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV99361270; called by muse, mutect2, varscan2
- CNOT7 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | catalogued as COSV100246498; called by muse, mutect2, varscan2
- CNP | c.588G>T p.K196N | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.48); catalogued as COSV101102866; called by muse, mutect2, varscan2
- CNPY2 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.062); catalogued as rs141635081; called by muse, mutect2, varscan2
- CNPY4 | c.273G>T p.E91D | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs1211225434, COSV99498745; called by muse, mutect2
- CNTD1 | c.317C>A p.S106Y | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV100162034; called by muse, mutect2, varscan2
- CNTN1 | c.2523+2T>C p.X841_splice | Splice Site (SNP) | VAF 5/8 reads (63%) | catalogued as COSV100750902; called by mutect2, varscan2
- CNTN1 | c.2551G>T p.E851* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100750903; called by muse, mutect2, varscan2
- CNTN4 | c.1136C>A p.A379D | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV100638783, COSV61871517; called by muse, mutect2, varscan2
- CNTN6 | c.1365-1G>T p.X455_splice | Splice Site (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100610010, COSV63182469; called by muse, varscan2
- CNTN6 | c.1389C>A p.S463R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100610012; called by muse, varscan2
- CNTN6 | c.2324A>C p.E775A | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100610013; called by muse, mutect2, varscan2
- CNTNAP2 | c.1493T>C p.F498S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV100662334; called by muse, mutect2, varscan2
- CNTNAP3 | c.3223A>C p.S1075R | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV99904019; called by muse, mutect2, varscan2
- CNTNAP5 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101442996; called by muse, mutect2, varscan2
- CNTNAP5 | c.2655G>T p.E885D | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as COSV70471890; called by muse, mutect2
- CNTRL | c.2723G>T p.R908I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV99440983; called by muse, mutect2, varscan2
- COBL | c.2009C>T p.P670L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1310990775, COSV99471127; called by muse, mutect2, varscan2
- COIL | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99537927; called by muse, mutect2, varscan2
- COL11A1 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100614926; called by muse, mutect2, varscan2
- COL12A1 | c.7771A>C p.S2591R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV100485323; called by muse, mutect2, varscan2
- COL13A1 | c.1970C>T p.T657M (on ENST00000398978 / NM_001130103.2; = p.T585M on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.06); catalogued as rs752607534, COSV100637247; called by muse, mutect2, varscan2
- COL14A1 | c.885A>C p.K295N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.383); catalogued as COSV52853147, COSV99917853; called by muse, mutect2, varscan2
- COL1A1 | c.1087T>G p.S363A | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99866300; called by muse, mutect2, varscan2
- COL20A1 | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753572248, COSV58925522; called by mutect2, varscan2
- COL22A1 | c.2469A>C p.E823D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.606); catalogued as COSV100276122; called by muse, varscan2
- COL22A1 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV57341538; called by muse, mutect2, varscan2
- COL24A1 | c.1583G>A p.G528E | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100992843; called by muse, varscan2
- COL25A1 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs748116911, COSV67658335; called by muse, mutect2, varscan2
- COL25A1 | c.298-1G>T p.X100_splice | Splice Site (SNP) | VAF 14/48 reads (29%) | catalogued as COSV101211137; called by muse, mutect2, varscan2
- COL4A2 | c.3195C>A p.F1065L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.27); catalogued as COSV100847169; called by muse, mutect2, varscan2
- COL4A3 | c.233A>C p.K78T | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.429); catalogued as COSV101169867; called by muse, mutect2, varscan2
- COL4A5 | c.3818G>A p.G1273D | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100086366; called by muse, mutect2, varscan2
- COL4A6 | c.433C>A p.L145I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100563248; called by muse, mutect2, varscan2
- COL4A6 | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs372504675, COSV100563251, COSV100564633; called by muse, mutect2, varscan2
- COL5A2 | c.4319G>T p.R1440I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100879978; called by muse, mutect2, varscan2
- COL5A3 | c.2779G>T p.E927* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV53408104; called by muse, mutect2, varscan2
- COL6A3 | c.9231G>T p.K3077N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs946842388, COSV55082584, COSV99798214; called by muse, mutect2, varscan2
- COL6A3 | c.281A>G p.N94S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV55083961; called by muse, mutect2, varscan2
- COLEC12 | c.1304T>C p.I435T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101231940; called by muse, mutect2, varscan2
- COMMD10 | c.608G>T p.*203Lext*19 | Nonstop Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV57240509, COSV99174496; called by muse, mutect2, varscan2
- COP1 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as rs991566021, COSV58169143; called by muse, mutect2, varscan2
- COPRS | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 15/75 reads (20%) | catalogued as COSV100188327; called by muse, mutect2, varscan2
- COQ5 | c.356A>G p.D119G | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99942172; called by muse, mutect2, varscan2
- CORO6 | c.879C>A p.Y293* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100801095; called by muse, mutect2, varscan2
- COX10 | c.258A>C p.K86N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV99885940; called by muse, mutect2, varscan2
- CP | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as rs1286440771, COSV52829767; called by muse, mutect2, varscan2
- CPA3 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as rs767770938, COSV99935931; called by muse, mutect2, varscan2
- CPA4 | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99744590; called by muse, mutect2, varscan2
- CPAMD8 | c.4507G>A p.E1503K (on ENST00000651564; = p.E1456K on NM_015692.5) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as rs776990790, COSV101488383; called by muse, mutect2, varscan2
- CPEB4 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.076); catalogued as COSV54172559; called by muse, mutect2, varscan2
- CPED1 | c.434-2A>C p.X145_splice | Splice Site (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100119910; called by muse, mutect2, varscan2
- CPNE5 | c.888G>T p.K296N | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1288938442, COSV99782379; called by muse, mutect2, varscan2
- CPSF6 | c.341T>G p.F114C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99878963; called by muse, mutect2, varscan2
- CPVL | c.353T>G p.F118C | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99605267; called by muse, mutect2, varscan2
- CPXCR1 | c.83G>T p.S28I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV99341946; called by muse, varscan2
- CR2 | c.2609T>G p.F870C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100889521; called by muse, mutect2, varscan2
- CRB2 | c.3557G>A p.G1186D | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1387667668, COSV100749513; called by muse, mutect2, varscan2
- CRBN | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99214030; called by muse, mutect2, varscan2
- CREB3L3 | c.104G>A p.G35D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV50261615; called by muse, mutect2, varscan2
- CRHBP | c.352C>A p.L118I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV99169438; called by muse, varscan2
- CRIM1 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as rs1365115540, COSV54867948; called by muse, mutect2, varscan2
- CRISP2 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as rs1296451511, COSV59254277; called by muse, mutect2
- CROCC | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100978042; called by muse, mutect2, varscan2
- CROT | c.518G>T p.R173I | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV100519293; called by muse, mutect2, varscan2
- CRPPA | c.1077A>C p.E359D (on ENST00000407010 / NM_001368197.1; = p.E309D on NM_001101417.4) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV101235286; called by muse, mutect2, varscan2
- CRPPA | c.457A>C p.I153L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as COSV101235287; called by muse, mutect2, varscan2
- CRYBG3 | c.5909T>C p.I1970T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV99476561; called by muse, mutect2, varscan2
- CRYBG3 | c.6648G>T p.K2216N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99476562; called by mutect2, varscan2
- CRYGC | c.497C>A p.S166Y | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM146465, COSV99965222; called by mutect2, varscan2
- CRYZL1 | c.903T>G p.L301= | Splice Region (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99280806; called by muse, mutect2
- CSE1L | c.676-1G>T p.X226_splice | Splice Site (SNP) | VAF 9/49 reads (18%) | catalogued as COSV99521809; called by muse, mutect2, varscan2
- CSF2RB | c.901C>A p.H301N | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV99453213, COSV99454263; called by muse, mutect2, varscan2
- CSMD1 | c.7804C>T p.R2602W (on ENST00000520002; = p.R2601W on NM_033225.6) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs371779170; called by muse, mutect2, varscan2
- CSMD1 | c.5524C>T p.Q1842* (on ENST00000520002; = p.Q1841* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV59345297; called by muse, mutect2, varscan2
- CSMD1 | c.1886A>C p.D629A (on ENST00000520002; = p.D628A on NM_033225.6) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100143068; called by muse, mutect2
- CSMD1 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV101213047; called by muse, mutect2
- CSMD3 | c.10153C>A p.L3385I (on ENST00000297405 / NM_001363185.1; = p.L3216I on NM_052900.3) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.083); catalogued as COSV99823447; called by muse, mutect2, varscan2
- CSMD3 | c.8825C>A p.S2942Y (on ENST00000297405 / NM_001363185.1; = p.S2773Y on NM_052900.3) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52173377; called by muse, mutect2, varscan2
- CSMD3 | c.5299A>G p.T1767A (on ENST00000297405 / NM_001363185.1; = p.T1663A on NM_052900.3) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as rs1563582651, COSV99823458; called by muse, mutect2, varscan2
- CSMD3 | c.5035C>T p.R1679W (on ENST00000297405 / NM_001363185.1; = p.R1575W on NM_052900.3) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368685063, COSV52136628; called by muse, mutect2, varscan2
- CSMD3 | c.4798C>A p.L1600I (on ENST00000297405 / NM_001363185.1; = p.L1496I on NM_052900.3) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV52158139, COSV99835789; called by muse, mutect2, varscan2
- CSMD3 | c.4477G>T p.G1493* (on ENST00000297405 / NM_001363185.1; = p.G1389* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV52098361, COSV99823471; called by muse, mutect2, varscan2
- CSMD3 | c.2803A>G p.I935V (on ENST00000297405 / NM_001363185.1; = p.I831V on NM_052900.3) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99823475; called by muse, varscan2
- CSNK1E | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV100724956; called by muse, varscan2
- CSRNP3 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV58785546; called by muse, mutect2, varscan2
3,850 further variants in this file (2,919 protein-altering or splice-affecting, 803 silent, 128 other) are not listed here.
